Somatic mutation profile of tumor specimen 0DUIYP from CCDI case PBCLJU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male.
Specimen 0DUIYP: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 68fde225-5298-43e1-bf96-23bb58f05c13.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUIWT (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0d9d0336-72e5-43db-8ad9-015b5421b975

The open-access MAF lists 13 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 2, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARL13B | c.1006C>T p.R336W (on ENST00000394222 / NM_001174150.2; = p.R229W on NM_144996.4) | Missense Mutation (SNP) | VAF 49/296 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs774235804; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHGB | c.832C>T p.R278C | Missense Mutation (SNP) | VAF 40/183 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.91); catalogued as rs755308357, COSV100972985; called by muse, mutect2, varscan2
- CNGA3 | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 153/371 reads (41%) | SIFT tolerated (0.56); PolyPhen benign (0.01); catalogued as rs1256677667, COSV55622065, COSV55623656; called by muse, mutect2, varscan2
- HAL | c.1168C>T p.R390C | Missense Mutation (SNP) | VAF 60/278 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.12); catalogued as rs367677601; called by muse, mutect2, varscan2
- DIS3 | c.1459G>C p.D487H | Missense Mutation (SNP) | VAF 20/321 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HNRNPA2B1 | c.943C>G p.P315A (on ENST00000354667 / NM_031243.3; = p.P303A on NM_002137.4) | Missense Mutation (SNP) | VAF 9/282 reads (3%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2
- LAMB4 | c.1360C>T p.P454S | Missense Mutation (SNP) | VAF 102/224 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLEKHM1 | c.1033A>G p.N345D | Missense Mutation (SNP) | VAF 23/289 reads (8%) | SIFT tolerated (0.82); PolyPhen benign (0); called by muse, mutect2
- TTN | c.22345G>T p.A7449S (on ENST00000591111; = p.A6522S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/318 reads (9%) | PolyPhen benign (0.015); called by muse, mutect2
- LRRC7 | c.3876T>C p.P1292= (on ENST00000651989 / NM_001370785.2; = p.P1259= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 18/350 reads (5%) | catalogued as COSV99228739; called by muse, mutect2
- NWD1 | c.1458G>A p.P486= | Silent (SNP) | VAF 33/109 reads (30%) | catalogued as rs549342239, COSV60340865; called by muse, mutect2, varscan2
- ABHD11 | c.463-44C>T | Intron (SNP) | VAF 90/168 reads (54%) | called by muse, mutect2, varscan2
- LRRIQ1 | c.*82G>A | 3'UTR (SNP) | VAF 11/77 reads (14%) | called by muse, mutect2, varscan2
